Somatic mutation profile of tumor specimen ALCH-B2Y7-TTP1-A (aliquot ALCH-B2Y7-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2Y7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 39.0 years (14,235 days).
Specimen ALCH-B2Y7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82926e70-d780-467b-9fd9-7e6027b0aec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2Y7-NB1-A (Blood Derived Normal), aliquot ALCH-B2Y7-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ac8a985-0468-48ec-bbe1-2bda533edcef

The open-access MAF lists 4 somatic variants for this specimen: 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRYGN | c.129C>T p.H43= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1014823575; called by muse, mutect2
- DUSP19 | c.120T>A p.I40= | Silent (SNP) | VAF 14/438 reads (3%) | catalogued as COSV61192876; called by muse, mutect2
- FA2H | c.843C>T p.I281= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs544646155; called by mutect2, varscan2
- ARHGAP33 | c.-26C>T | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
